Surgical pathology report (de-identified scan), TCGA case TCGA-BK-A0CB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-BK-A0CB-01A (Primary Tumor).

[page 1 of 5]
1CD-0-3

adenocarcinoma, endometrioid, Nos 8380/3
Site: endometrium C54.1 lu 9/3/11

SPECIMEN

The specimen is received in five parts, labeled as follows:

- A. Uterus, cervix, ovaries, tubes, bilateral parametria, upper vagina
- B. Right pelvic lymph node
- C. Right periaortic lymph node
- D. Left pelvic lymph node
- E. Left periaortic lymph node

CLINICAL NOTES

PRE-OP DIAGNOSIS: Endometrial cancer.

GROSS DESCRIPTION

A. Received fresh, labeled "uterus, cervix, ovaries, tubes, bilateral parametria, upper vagina", is a 149 gram, 5.5 x 5.5 x 4.5 cm. symmetrical uterine corpus, with attached 3.5 cm. cervix and marked adnexa. The serosa is smooth tan-pink-red.

A

thin rim of wrinkled pale tan apparent vaginal mucosa circumferences

the 4.2 x 3.8 cm. dusky tan-pink-red ectocervix. The patent os measures 1 x 0.3 cm. The anterior paracervical surface is inked blue and the posterior paracervical surface is inked black. On opening, the cervical canal contains soft tan-white tumor, which extends into and filled the distorted 4 x 2.5 cm. endometrial cavity. Sectioning through the cervix and lower uterine segment reveals glistening tan-white tumor, which measures up to 2 cm. in thickness and extends to within 0.2 cm. of the inked paracervical surface. The tumor throughout the endometrial cavity measures up

to

2.2 cm. in thickness, involving greater than 75% of the myometrium grossly. The myometrium is tan-pink and measures up to 2 cm. in thickness. The 2.4 x 2.2 x 1.6 cm., rubbery tan-gold left ovary shows pale tan stroma on sectioning by identifiable corpora albicantia. The discontinuous-appearing fimbriated pink-purple

left

fallopian tube measures 5.5 cm. in length and averages 0.5 cm. in diameter, with a pinpoint to stellate lumen on sectioning.

Received

[page 2 of 5]
GROSS DESCRIPTION

separately within the specimen container is a 4 x 3.4 x 2.5 cm. attenuated tan-gold ovary and associated, fimbriated, 4 cm. pink-purple fallopian tube segment. On sectioning, the ovary is cystic, containing a copious amount of grumous, greasy tan-gold debris and brown hair. A tubercle is not identified grossly. Residual ovarian stroma is pale tan with identifiable corpora albicantia. The fallopian tube segment averages 0.5 cm. in diameter with a pinpoint to stellate lumen on sectioning. Representative sections are submitted in twenty-two blocks, as labeled. RS-22

BLOCK SUMMARY: 1-4 - Vaginal margin sequentially beginning at 12 to 3 o'clock; 5,6 - anterior cervix/LUS (point of continuity inked orange); 7-9 - representative cervix containing tumor from 2 to 5 o'clock; 10,11 - posterior cervix/LUS (point of continuity inked green); 12,13 - representative cervix, including tumor from 7 to 11 o'clock; 14-16 - representative anterior endomyometrium with tumor full thickness sequentially from fundus to LUS; 16-19 - representative posterior endomyometrium, including tumor full thickness sequentially from fundus to LUS; 20 - left tube and ovary; 21,22 - separately received tube and ovary.

a B. Received fresh, labeled "right pelvic lymph node", is 7.4 x 6.8 x 3.4 cm. aggregate of soft, lobulated golden-yellow adipose tissue. A few soft to slightly rubbery tan-pink-gold tissues, in keeping with lymph nodes, measuring up to 5.4 cm. in greatest dimension, are recovered. The lymphoid tissues are entirely submitted in nine blocks, as labeled. RS-9

BLOCK SUMMARY: 1 - Two whole nodes; 2,3; 4,5 - one bisected node per pair of cassettes (one-half per cassette); 6-9 - quadrisectioned largest node.

C. Received in formalin, labeled "right periaortic lymph

[page 3 of 5]
GROSS DESCRIPTION

node", is a 6 x 3.6 x 1.7 cm. portion of soft, lobulated golden-yellow adipose tissue. A few soft to rubbery, lobulated tan-pink-gold tissues, in keeping with lymph nodes, measuring up to 3.2 cm. in greatest dimension, are recovered. The lymphoid tissues are entirely submitted in five blocks, as labeled. RS-5

BLOCK SUMMARY: 1 - Two whole nodes; 2,3 - one bisected node per cassette; 4,5 - bisected largest node (one-half per cassette).

D. Received in formalin, labeled "left pelvic lymph node",

is a 7.5 x 7.5 x 3.3 cm. aggregate of soft, lobulated golden-yellow adipose tissue. Several soft to slightly rubbery tan-pink-gold tissues, in keeping with lymph nodes, measuring up to 4.3 cm. in greatest dimension, are recovered. The lymphoid tissues are entirely submitted in eight blocks, as labeled. RS-8

BLOCK SUMMARY: 1 - Four whole lymph nodes; 2,3 - one bisected lymph node per cassette; 4,5 - one bisected lymph node (one-half per cassette); 6-8 - trisected largest lymph node (one-third per cassette).

E. Received in formalin, labeled "left periaortic lymph node", is a 4.7 x 3.8 x 2.3 cm. portion of soft, lobulated golden-yellow adipose tissue. A few soft to rubbery tan-pink-gold tissues, in keeping with lymph nodes, measuring up to 4 cm. in greatest dimension, are recovered. The lymphoid tissues are entirely submitted in six blocks, as labeled. RS-6

BLOCK SUMMARY: 1 - Two whole nodes; 2 - one bisected node; 3-6 - quadrisected largest node (one-quarter per cassette).

[page 4 of 5]
MICROSCOPIC DESCRIPTION

A. The following template applies to the hysterectomy specimen.

Histologic type: Endometrioid adenocarcinoma with squamous differentiation.

Histologic grade: 2

Myometrial invasion:

1.3 cm depth of invasion

1.7 cm depth of myometrial thickness

76% of myometrial wall

Cervix: Extensively involved by carcinoma replacing the stromal connective tissue.

Primary tumor (pT) TNM: pT2b (FIGO IIB)

Margins of resection: Uninvolved.

Vascular invasion: foci suspicious.

Regional lymph nodes (pN): Positive as described below (pN1).

Distant metastasis (pM): Cannot be evaluated by the specimen (pMX).

Other findings: There is a mature cystic teratoma of the left ovary.

B. The right pelvic lymph nodes demonstrate six lymph nodes with no evidence of metastasis.

C. The right periaortic lymph nodes demonstrate

metastatic

disease in one of four lymph nodes.

D. The left pelvic lymph nodes demonstrate seven lymph nodes with no evidence of metastasis.

E. The left periaortic lymph nodes demonstrate metastatic disease in one of four lymph nodes.

5,4x4

[page 5 of 5]
DIAGNOSIS

A. Uterus, cervix, resection:

- Adenocarcinoma, endometrioid type, by direct extension from the uterine corpus, extensively involving the cervical stroma.

Uterus, endomyometrium, resection

- Adenocarcinoma, endometrioid type, grade 2 with squamous differentiation.
- Depth of invasion 76% through myometrial wall.

Ovary, left, resection

- Mature cystic teratoma.

Ovary, right, resection

- No evidence of malignancy.

Fallopian tubes, right and left, resection

- No pathologic diagnosis.

B. Right pelvic lymph nodes, resection

- No evidence of metastasis in six lymph nodes (0/6).

C. Right periaortic lymph nodes, resection

- Metastatic carcinoma involving one of four lymph nodes (1/4).

D. Left pelvic lymph nodes, resection

- No evidence of metastasis in seven lymph nodes (0/7).

E. Left periaortic lymph nodes, resection

- Metastatic carcinoma involving one of four lymph nodes (1/4).

-----, M.D, (Electronic Signature)

--- End Of Report ---

HPA Discrepancy		☒

Source: NCI Genomic Data Commons file 549ee87a-6af1-43ce-9903-778ccf0b394d (TCGA-BK-A0CB.37923E3D-3CCB-41DB-8F30-C19FDE7407CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).